Somatic mutation profile of tumor specimen TCGA-D3-A3CC-06A (aliquot TCGA-D3-A3CC-06A-11D-A19A-08) from TCGA case TCGA-D3-A3CC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.7 years (26,173 days).
Specimen TCGA-D3-A3CC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa93bfb1-53f6-497e-9b83-92a79e527ea9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3CC-10A (Blood Derived Normal), aliquot TCGA-D3-A3CC-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b29ebe78-75ca-4e2c-9547-7d86375aed4d

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Frame Shift Ins 2, Translation Start Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP10 | c.1850G>A p.C617Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.44); catalogued as COSV60606427; called by muse, mutect2, varscan2
- CIC | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.628); catalogued as COSV50656350, COSV50661745; called by muse, mutect2, varscan2
- DNAH17 | c.5165C>T p.A1722V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV67760829; called by muse, mutect2
- DZIP1L | c.2091dup p.M698Yfs*20 | Frame Shift Ins (INS) | VAF 63/357 reads (18%) | catalogued as rs747435690; called by pindel, varscan2
- EIF3G | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.828); catalogued as rs754638574, COSV53455961; called by muse, mutect2, varscan2
- FAT4 | c.1900C>G p.L634V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67899377; called by muse, mutect2, varscan2
- FAT4 | c.14887G>A p.E4963K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV58707848; called by muse, mutect2, varscan2
- FLG2 | c.5174G>A p.G1725E | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV66173015; called by muse, mutect2, varscan2
- HGF | c.1311G>C p.E437D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV55956496; called by muse, mutect2, varscan2
- HSP90AB1 | c.823A>G p.K275E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.21); catalogued as COSV62336254; called by muse, mutect2
- IL17RD | c.1596C>A p.N532K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56342648; called by muse, mutect2, varscan2
- KCTD20 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV54804732; called by muse, varscan2
- KLK8 | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51593877; called by muse, varscan2
- NDST1 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.485); catalogued as rs770708585, COSV55790697; called by mutect2, varscan2
- NSUN3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 80/188 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs546505122, COSV58937860; called by muse, varscan2
- PDE2A | c.1842C>G p.D614E | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57813308; called by muse, mutect2, varscan2
- PMEPA1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs571813112; called by muse, mutect2
- PPP6R2 | c.1223C>A p.T408K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV53298206; called by muse, mutect2, varscan2
- RPA2 | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.574); catalogued as COSV57878818; called by muse, mutect2
- SPTBN4 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV58958230; called by muse, mutect2, varscan2
- VRK3 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57467895; called by muse, mutect2, varscan2
- VRK3 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766478278, COSV100371802; called by muse, mutect2, varscan2
- WBP11 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV53764753; called by muse, mutect2
- WIPI2 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV56591516, COSV99059032; called by muse, varscan2
- ZMYND10 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs373018717, COSV51603976; called by muse, mutect2
- ZNF45 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99524238; called by muse, mutect2, varscan2
- ZNF45 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54194682; called by muse, mutect2, varscan2
- CD44 | c.933_937dup p.R313Hfs*34 | Frame Shift Ins (INS) | VAF 21/104 reads (20%) | called by mutect2, varscan2
- ALPK2 | c.4899G>A p.E1633= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV64496926; called by muse, mutect2, varscan2
- B4GALNT1 | c.885C>G p.L295= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as COSV57544782; called by muse, mutect2, varscan2
- DSCAM | c.4194T>G p.S1398= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV68035691, COSV68039722; called by muse, mutect2, varscan2
- KRT23 | c.240C>T p.N80= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV52927454; called by muse, mutect2, varscan2
- KRTAP1-3 | c.42C>T p.C14= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV60337012; called by muse, mutect2, varscan2
- PCNX1 | c.6165G>T p.G2055= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs377236793; called by muse, mutect2, varscan2
- ZXDA | c.2055G>A p.Q685= | Silent (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- AP000769.5 | chr11:65498218 A>T | 5'Flank (SNP) | VAF 11/36 reads (31%) | catalogued as rs137885794; called by muse, mutect2, varscan2
- XIST | n.10354T>A | RNA (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
